Gene-level copy-number profile of tumor specimen TCGA-BR-A4J6-01A from TCGA case TCGA-BR-A4J6, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cardia, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 69.2 years (25,279 days).
Specimen TCGA-BR-A4J6-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.a3b225e4-3c6f-41ec-b5f7-089dca1d4738.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-BR-A4J6-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/abc814de-5e05-43a6-81f7-7122ad0f3c5f

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 12,614; copy number 2: 44,759; copy number 3: 2,300; copy number 4: 36; copy number 6: 34; copy number 7: 5; copy number 9: 10; copy number 10: 2; copy number 11: 11; copy number 13: 49.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-BR-A4J6-01A-11D-A253-01): tumor purity 0.62, ploidy 1.87, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 111 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:104,998,406–105,698,218, 4 genes, copy number 6: AL591888.1, CDK4P1, LINC01676, SEPTIN2P1.
- chr1:107,056,674–107,505,448, 3 genes, copy number 7–10: PRMT6, NTNG1, NDUFA4P1.
- chr1:113,696,831–113,901,237, 7 genes, copy number 11 (within-gene range 1–11): PHTF1, AL133517.1, RSBN1, AL137856.1, PTPN22, AP4B1-AS1, BCL2L15.
- chr12:46,970,504–47,236,662, 4 genes, copy number 7 (within-gene range 1–7): AC079906.1, AMIGO2, PCED1B, IFITM3P6.
- chr12:49,064,676–49,189,080, 9 genes, copy number 6: RHEBL1, AC011603.4, DHH, AC011603.1, LMBR1L, TUBA1B, AC011603.2, Y_RNA, TUBA1A.
- chr12:49,196,784–49,197,062, 1 gene, copy number 6: Metazoa_SRP.
- chr12:67,989,445–70,243,379, 59 genes, copy number 9–13 (within-gene range 1–13): IFNG-AS1, RPL39P28, HNRNPA1P70, AC007458.1, IFNG, IL26, IL22, MDM1, LINC02384, AC022511.1, AC008033.3, AC008033.1, AC008033.2, RPSAP12, Metazoa_SRP, RAP1B, RPL10P12, SNORA70G, ATP5PDP4, AC090061.1, RPL7P42, NUP107, KRT8P39, SLC35E3, AC025423.3, MDM2, AC025423.1, AC025423.4, AC025423.2, CPM, RNU7-4P, AC025423.5, PRELID2P1, AC127894.1, CPSF6, MIR1279, C1GALT1P1, AC020656.2, LYZ, AC020656.1, YEATS4, RN7SL804P, RPS26P45, LINC02373, FRS2, MIR3913-1, MIR3913-2, CCT2, LRRC10, BEST3, AC025263.3, AC025263.1, RAB3IP, AC025263.2, MYRFL, PRANCR, AC078922.1, LINC02821, AC092881.2.
- chr12:73,648,666–73,846,188, 4 genes, copy number 11: AC087879.1, RNU6-1012P, LINC02445, U8.
- chr12:95,551,582–96,102,249, 16 genes, copy number 6 (within-gene range 1–6): PGAM1P5, Y_RNA, NTN4, AC090001.1, RNU6-247P, LINC02410, SNRPF, CCDC38, AC090001.2, AMDHD1, HAL, AC007298.2, LTA4H, AC007298.1, YPEL5P3, RN7SL88P.
- chr12:106,495,958–106,774,926, 4 genes, copy number 6 (within-gene range 4–6): AC079385.1, RFX4, AC079385.2, AC079385.3.

Autosomal genes at a single copy (total copy number 1): 10,193. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
